Somatic mutation profile of tumor specimen TCGA-EK-A2PL-01A (aliquot TCGA-EK-A2PL-01A-11D-A18J-09) from TCGA case TCGA-EK-A2PL, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Age at diagnosis: 36.6 years (13,384 days).
Specimen TCGA-EK-A2PL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad9d25f9-74a3-4c5c-acd6-d49ebdb55d8e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EK-A2PL-10A (Blood Derived Normal), aliquot TCGA-EK-A2PL-10A-01D-A18J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/458633b1-ff67-44e7-834c-34b4a0009f33

The open-access MAF lists 180 somatic variants for this specimen: 143 protein-altering or splice-affecting, 34 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 125, Silent 34, Nonsense Mutation 13, Frame Shift Ins 2, Frame Shift Del 2, RNA 2, Translation Start Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1435C>G p.R479G (on ENST00000281708 / NM_001349798.2; = p.R399G on NM_018315.5) | Missense Mutation (SNP) | VAF 19/31 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747241612, COSV55894141, COSV55894999, COSV55908957; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TGFBR2 | c.1489C>T p.R497* | Nonsense Mutation (SNP) | VAF 7/18 reads (39%) | catalogued as rs863223852, CM063204, COSV55443474; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ACLY | c.491A>T p.D164V | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV100709902; called by muse, mutect2
- ADAMTS3 | c.2045G>A p.G682E | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54385889; called by muse, mutect2, varscan2
- AHNAK | c.12415A>C p.K4139Q | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57204844; called by muse, mutect2, varscan2
- ANAPC15 | c.14T>G p.F5C | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99921467; called by muse, mutect2
- ANKRD17 | c.6829C>T p.Q2277* | Nonsense Mutation (SNP) | VAF 7/30 reads (23%) | catalogued as COSV58215958; called by muse, mutect2, varscan2
- ANKS1B | c.3454G>C p.D1152H (on ENST00000547776 / NM_152788.4; = p.D318H on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/131 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59115521; called by muse, mutect2, varscan2
- ANO6 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100263881; called by muse, mutect2
- AP2A2 | c.120C>G p.I40M | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59958247; called by muse, mutect2, varscan2
- AP3B1 | c.1946G>A p.R649Q | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748191084, COSV54877031; called by muse, mutect2, varscan2
- ARFIP2 | c.982C>T p.R328W | Missense Mutation (SNP) | VAF 16/18 reads (89%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as rs773493084, COSV54446252; called by muse, mutect2, varscan2
- ARHGEF11 | c.2506C>G p.Q836E | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV59352590; called by muse, mutect2, varscan2
- ATP2B3 | c.2689C>G p.L897V | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV54840660, COSV54841127; called by muse, mutect2, varscan2
- ATRX | c.5288A>T p.N1763I | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64872142; called by muse, mutect2, varscan2
- CACNA1C | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.98); catalogued as rs1447615624; called by muse, mutect2
- CAD | c.1357C>G p.L453V | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV53024038; called by muse, mutect2, varscan2
- CAMK1G | c.351G>T p.E117D | Missense Mutation (SNP) | VAF 56/109 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99152090; called by muse, mutect2, varscan2
- CCDC77 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs565946457, COSV53472011; called by muse, mutect2, varscan2
- CD101 | c.14C>G p.S5* | Nonsense Mutation (SNP) | VAF 20/40 reads (50%) | catalogued as COSV56716344; called by muse, varscan2
- CDK10 | c.184G>C p.D62H | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as COSV58414061; called by muse, mutect2, varscan2
- CHD4 | c.4789G>A p.E1597K (on ENST00000357008 / NM_001363606.2; = p.E1610K on NM_001273.5) | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.025); catalogued as COSV58895596; called by muse, mutect2, varscan2
- CYP4F11 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.181); catalogued as COSV56125778; called by muse, mutect2, varscan2
- DGKA | c.2114C>T p.T705M | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs760712689, COSV59384370; called by muse, mutect2, varscan2
- EPHA3 | c.2033A>C p.D678A | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as COSV60695407; called by muse, mutect2, varscan2
- ETV2 | c.229G>A p.G77R | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.762); catalogued as COSV66842101; called by muse, mutect2, varscan2
- FMO1 | c.465G>C p.L155F | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.928); catalogued as COSV61444756; called by muse, mutect2, varscan2
- GCG | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV64960875; called by muse, mutect2, varscan2
- GCKR | c.661G>C p.D221H | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); catalogued as COSV53106648; called by muse, mutect2, varscan2
- GEN1 | c.2405C>G p.S802C | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs752304758, COSV58055444; called by muse, mutect2, varscan2
- GMIP | c.1412G>C p.G471A | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV52554474; called by muse, mutect2, varscan2
- GREB1 | c.5592C>G p.I1864M | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.301); catalogued as COSV52181518; called by muse, mutect2, varscan2
- GRM7 | c.710C>T p.S237F | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.404); catalogued as COSV63131113; called by muse, mutect2, varscan2
- GTPBP4 | c.1697G>A p.R566Q | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.217); catalogued as rs773394843, COSV52987180; called by muse, mutect2, varscan2
- GUCY2F | c.1211C>T p.S404L | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV54298965; called by muse, mutect2, varscan2
- HDDC2 | c.87_88del p.R29Sfs*34 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | catalogued as rs1236389893; called by pindel, varscan2
- HEATR1 | c.4621G>A p.E1541K | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1314926775, COSV63979896; called by muse, mutect2
- HELZ2 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as rs1332638824, COSV64409116; called by muse, mutect2, varscan2
- HERC1 | c.4342C>T p.R1448W | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs865926938, COSV71246074; called by muse, mutect2, varscan2
- HFM1 | c.2345G>A p.R782K | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.336); catalogued as COSV54022115, COSV54029145; called by muse, mutect2, varscan2
- HIF1A | c.340G>C p.D114H | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV60188297; called by muse, mutect2, varscan2
- HLA-A | c.627dup p.K210Qfs*11 | Frame Shift Ins (INS) | VAF 48/103 reads (47%) | catalogued as rs199474609; called by mutect2, varscan2
- HPD | c.1114G>C p.E372Q | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1316404476, COSV100000078, COSV56641177; called by muse, mutect2, varscan2
- IGSF9B | c.625C>T p.R209* | Nonsense Mutation (SNP) | VAF 24/72 reads (33%) | catalogued as rs566589696, COSV58064307; called by muse, mutect2, varscan2
- INPP4B | c.2666T>C p.V889A | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as COSV53712394; called by muse, mutect2, varscan2
- IRS1 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59333074; called by muse, mutect2, varscan2
- KATNIP | c.475G>C p.D159H | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV55174311; called by muse, mutect2, varscan2
- KDM1B | c.1936G>A p.E646K (on ENST00000449850; = p.E413K on NM_153042.4) | Missense Mutation (SNP) | VAF 68/94 reads (72%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV52808845; called by muse, mutect2, varscan2
- KDM2A | c.373C>T p.Q125* | Nonsense Mutation (SNP) | VAF 23/66 reads (35%) | catalogued as COSV67081221; called by muse, mutect2, varscan2
- KMT2E | c.5086C>G p.P1696A | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.111); catalogued as COSV57569923; called by muse, mutect2, varscan2
- KRT2 | c.1895C>T p.S632F | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as COSV100548651; called by muse, mutect2
- KRT7 | c.134C>G p.S45* | Nonsense Mutation (SNP) | VAF 4/10 reads (40%) | catalogued as COSV59330763; called by muse, varscan2
- LIG3 | c.634G>T p.V212L | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV52009953, COSV99253149; called by muse, mutect2, varscan2
- LONRF2 | c.1795G>A p.V599M | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs143848902; called by muse, mutect2
- LRFN1 | c.1279C>T p.R427W | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV50434815; called by muse, mutect2, varscan2
- LRRC8E | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV60717052; called by muse, mutect2, varscan2
- MACC1 | c.2317C>G p.R773G | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV60541074, COSV60545538; called by muse, mutect2, varscan2
- MCM10 | c.727C>G p.Q243E (on ENST00000484800 / NM_182751.3; = p.Q242E on NM_018518.5) | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.11); catalogued as COSV66333217, COSV66333644; called by muse, mutect2, varscan2
- MCM3AP | c.1477A>C p.S493R | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.048); catalogued as COSV52436620; called by muse, mutect2
- ME2 | c.1099C>T p.H367Y | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV58422365; called by muse, mutect2, varscan2
- MED23 | c.3609G>A p.M1203I | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.299); catalogued as COSV63430446; called by muse, mutect2, varscan2
- MED24 | c.268C>T p.R90W | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as rs747015081, COSV62417321; called by muse, mutect2, varscan2
- MFSD14A | c.767C>A p.S256Y | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs1392864747, COSV64514377; called by muse, mutect2, varscan2
- MIEF1 | c.1248C>G p.I416M | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs1386282092, COSV57477689; called by muse, mutect2, varscan2
- MORC3 | c.1697C>T p.S566L | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV68687815; called by muse, varscan2
- MTMR2 | c.238C>G p.P80A | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV60578661; called by mutect2, varscan2
- MYEF2 | c.841G>C p.E281Q | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51046072, COSV99981569; called by muse, mutect2, varscan2
- NBR1 | c.1841C>T p.A614V | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.054); catalogued as COSV57831024; called by muse, mutect2, varscan2
- NRDC | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.268); catalogued as COSV61401881; called by muse, mutect2, varscan2
- OSMR | c.202C>T p.Q68* | Nonsense Mutation (SNP) | VAF 17/125 reads (14%) | catalogued as COSV57081493; called by muse, mutect2, varscan2
- PCDHA5 | c.1393G>T p.E465* | Nonsense Mutation (SNP) | VAF 16/117 reads (14%) | catalogued as rs782693358, COSV65349767; called by muse, mutect2, varscan2
- PCNA | c.574G>T p.E192* | Nonsense Mutation (SNP) | VAF 13/35 reads (37%) | catalogued as COSV52531758; called by muse, mutect2, varscan2
- PCYOX1 | c.1012C>T p.Q338* | Nonsense Mutation (SNP) | VAF 11/29 reads (38%) | catalogued as rs747947804, COSV52475619, COSV99713197; called by muse, mutect2, varscan2
- PEX14 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as rs1262518105, COSV63059931; called by muse, mutect2, varscan2
- PHF23 | c.64C>A p.Q22K | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.258); catalogued as rs926940109, COSV50034744; called by muse, mutect2
- PID1 | c.471C>A p.H157Q (on ENST00000354069 / NM_001330156.1; = p.H155Q on NM_017933.5) | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.313); catalogued as COSV62472994; called by muse, mutect2, varscan2
- PIGR | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.31); PolyPhen benign (0.159); catalogued as COSV62903318; called by muse, mutect2, varscan2
- PKD1L2 | c.199C>G p.Q67E | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV61412147; called by muse, mutect2, varscan2
- POLR1A | c.2433G>C p.K811N | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV55689638; called by muse, mutect2, varscan2
- PPL | c.2656G>C p.D886H | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.078); catalogued as COSV52166044; called by muse, mutect2, varscan2
- PPP2R2C | c.1299C>G p.N433K | Missense Mutation (SNP) | VAF 33/57 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59442173; called by muse, mutect2, varscan2
- PPP2R5C | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.283); catalogued as COSV100159997; called by muse, varscan2
- PRICKLE4 | c.865G>C p.E289Q (on ENST00000359201; = p.E329Q on NM_013397.6) | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.006); catalogued as COSV59253699, COSV59253790; called by muse, mutect2, varscan2
- PROK1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.682); catalogued as COSV54764384; called by muse, mutect2
- PTPRB | c.2534A>C p.D845A | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54233480; called by muse, mutect2, varscan2
- PUDP | c.91C>G p.Q31E | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as COSV66903314; called by muse, mutect2, varscan2
- RAI1 | c.2488G>A p.E830K | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as rs754955930, COSV55389598; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RAI1 | c.2605G>C p.E869Q | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55389618; called by muse, mutect2, varscan2
- REL | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54362588; called by muse, mutect2, varscan2
- REV3L | c.2129C>G p.S710C | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.417); catalogued as COSV62615714; called by muse, mutect2, varscan2
- RGS14 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV68770910; called by muse, varscan2
- RYR3 | c.12910G>A p.E4304K (on ENST00000389232; = p.E4305K on NM_001036.6) | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.259); catalogued as COSV101213250, COSV66779248; called by muse, mutect2, varscan2
- SALL3 | c.2113C>T p.R705W | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748726882, COSV73305799; called by muse, mutect2, varscan2
- SCN8A | c.5572G>A p.D1858N | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV61977041; called by muse, mutect2, varscan2
- SEC23A | c.344C>G p.S115C | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); catalogued as COSV56971216; called by muse, mutect2, varscan2
- SETDB1 | c.3817G>C p.E1273Q (on ENST00000271640 / NM_001366417.1; = p.E1272Q on NM_012432.4) | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.047); catalogued as COSV54977887; called by muse, mutect2, varscan2
- SF1 | c.922C>T p.R308W | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs777252081, COSV57111752; called by muse, mutect2, varscan2
- SHOC1 | c.827C>G p.S276C | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.81); catalogued as COSV59497915; called by muse, mutect2, varscan2
- SKIDA1 | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.398); catalogued as COSV71610458; called by muse, mutect2, varscan2
- SKOR1 | c.2137G>A p.D713N | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as COSV58244084; called by muse, mutect2, varscan2
- SLITRK3 | c.2158G>T p.G720W | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.815); catalogued as rs748687866, COSV53845956, COSV53852458; called by muse, mutect2, varscan2
- SMTN | c.205C>T p.Q69* | Nonsense Mutation (SNP) | VAF 13/34 reads (38%) | catalogued as COSV60775558; called by muse, mutect2, varscan2
- SOGA3 | c.1116G>C p.E372D | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.942); catalogued as COSV64105204; called by muse, mutect2, varscan2
- SPATA9 | c.109G>C p.D37H | Missense Mutation (SNP) | VAF 24/36 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57223304; called by muse, mutect2, varscan2
- SPINDOC | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.059); catalogued as COSV53692002; called by muse, mutect2, varscan2
- SYNE1 | c.2350G>C p.E784Q (on ENST00000367255 / NM_182961.4; = p.E791Q on NM_033071.3) | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.41); PolyPhen benign (0.013); catalogued as COSV54916345; called by muse, mutect2, varscan2
- TAF2 | c.231C>G p.I77M | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.153); catalogued as COSV65416822; called by muse, varscan2
- TENM1 | c.8168G>C p.G2723A | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64425845; called by muse, mutect2, varscan2
- TENM1 | c.4204C>T p.R1402C | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1332169292, COSV64425851; called by muse, mutect2, varscan2
- TEX15 | c.6169G>A p.E2057K (on ENST00000256246; = p.E2440K on NM_001350162.2) | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.801); catalogued as rs1563232357, COSV56342143; called by muse, mutect2, varscan2
- TMEM192 | c.803C>G p.P268R | Missense Mutation (SNP) | VAF 52/82 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.316); catalogued as COSV60584631; called by muse, mutect2, varscan2
- TMEM52B | c.303C>G p.I101M (on ENST00000381923 / NM_001079815.1; = p.I81M on NM_153022.4) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.199); catalogued as rs920612867, COSV53727500; called by muse, mutect2, varscan2
- TNFRSF21 | c.1224C>G p.I408M | Missense Mutation (SNP) | VAF 49/76 reads (64%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.779); catalogued as COSV57280308; called by muse, mutect2, varscan2
- TNS3 | c.2498G>A p.R833K | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.053); catalogued as COSV60787271; called by muse, mutect2, varscan2
- TRIM54 | c.391G>C p.E131Q | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.392); catalogued as COSV56082190; called by muse, mutect2, varscan2
- TSEN34 | c.858G>C p.K286N | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778367406, COSV55474489; called by muse, mutect2, varscan2
- TTN | c.30844G>A p.E10282K (on ENST00000591111; = p.E9355K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/37 reads (27%) | PolyPhen benign (0.009); catalogued as COSV59866104; called by muse, mutect2, varscan2
- TUT1 | c.614C>G p.S205C | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53468882; called by muse, mutect2, varscan2
- UGT2B17 | c.433A>G p.K145E | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.233); catalogued as COSV58500926; called by muse, mutect2, varscan2
- UNC13A | c.883G>C p.E295Q | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.533); catalogued as rs1400353250, COSV53189194; called by muse, mutect2, varscan2
- USP34 | c.1891C>G p.H631D | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs762517828, COSV68398561; called by muse, mutect2, varscan2
- USP43 | c.933G>C p.K311N | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.375); catalogued as COSV99557047; called by muse, mutect2
- USP47 | c.2363G>C p.R788T (on ENST00000399455 / NM_001372095.1; = p.R700T on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.537); catalogued as COSV60461133; called by muse, mutect2, varscan2
- WDFY3 | c.4004C>T p.T1335I | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.45); catalogued as rs144349462; called by muse, mutect2, varscan2
- WDR36 | c.1087G>C p.D363H | Missense Mutation (SNP) | VAF 23/36 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV72411041; called by muse, mutect2, varscan2
- WDR72 | c.844C>G p.Q282E | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs759928753, COSV64742078; called by muse, mutect2, varscan2
- WLS | c.1070G>A p.R357K | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.926); catalogued as COSV52037713; called by muse, mutect2, varscan2
- XRN2 | c.365C>G p.S122* | Nonsense Mutation (SNP) | VAF 7/30 reads (23%) | catalogued as COSV101018552, COSV65868213; called by muse, mutect2, varscan2
- ZFC3H1 | c.1138C>T p.Q380* | Nonsense Mutation (SNP) | VAF 36/86 reads (42%) | catalogued as COSV66430431; called by muse, mutect2, varscan2
- ZHX3 | c.2008G>A p.E670K | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.043); catalogued as rs528894752, COSV58381007; called by muse, varscan2
- ZNF169 | c.465G>C p.K155N | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.48); PolyPhen benign (0.062); catalogued as COSV61763227; called by muse, mutect2, varscan2
- ZNF180 | c.1932G>C p.L644F | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.059); catalogued as COSV55419898; called by muse, mutect2, varscan2
- ZNF511-PRAP1 | c.739C>G p.Q247E | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.02); catalogued as COSV53369268; called by muse, mutect2, varscan2
- ZNF628 | c.2653G>C p.E885Q | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.743); catalogued as COSV52698126; called by muse, mutect2, varscan2
- ZNF711 | c.2213G>A p.C738Y | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52151729; called by muse, mutect2, varscan2
- ZNF763 | c.1072C>A p.H358N (on ENST00000358987 / NM_001367172.2; = p.H361N on NM_001012753.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV59687208; called by muse, mutect2, varscan2
- ZNF800 | c.1135C>G p.Q379E | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0.181); catalogued as COSV56173880; called by mutect2, varscan2
- ZNF83 | c.942G>C p.E314D | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as COSV56528646; called by muse, mutect2, varscan2
- ZZEF1 | c.1987G>A p.E663K | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV101068068; called by muse, mutect2
- ABCA12 | c.1221dup p.S408Ifs*9 (on ENST00000272895 / NM_173076.3; = p.S90Ifs*9 on NM_015657.3) | Frame Shift Ins (INS) | VAF 18/90 reads (20%) | called by mutect2, pindel, varscan2
- ARRDC3 | c.571del p.I191Yfs*3 | Frame Shift Del (DEL) | VAF 13/23 reads (57%) | called by mutect2, pindel, varscan2
- MLLT6 | c.235G>C p.D79H | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRAV13-2 | c.193C>G p.Q65E | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.38); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- ADD1 | c.75C>T p.F25= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as rs199855248, COSV53266630; ClinVar: likely benign; called by muse, mutect2, varscan2
- ARHGEF18 | c.1101G>T p.L367= (on ENST00000359920 / NM_001130955.2; = p.L263= on NM_015318.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- ATP4A | c.27C>G p.L9= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV52865879; called by muse, mutect2, varscan2
- CFAP43 | c.3774G>A p.Q1258= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV100829472; called by muse, mutect2, varscan2
- CIB4 | c.557G>A p.*186= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV56599256; called by muse, mutect2, varscan2
- CTSD | c.1146C>G p.L382= | Silent (SNP) | VAF 40/61 reads (66%) | catalogued as rs1030148662, COSV52587212, COSV52588233; called by muse, mutect2, varscan2
- DDRGK1 | c.57C>G p.L19= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV63226521; called by muse, mutect2, varscan2
- DOCK8 | c.3327G>A p.L1109= | Silent (SNP) | VAF 36/57 reads (63%) | catalogued as COSV66617935; called by muse, mutect2, varscan2
- FAM98A | c.168C>T p.L56= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV53209353; called by muse, mutect2, varscan2
- GARRE1 | c.2655G>C p.R885= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as COSV100209732; called by muse, mutect2
- GBP7 | c.561G>C p.L187= | Silent (SNP) | VAF 22/47 reads (47%) | catalogued as COSV54008284; called by muse, mutect2, varscan2
- GUCY1A1 | c.1807C>T p.L603= | Silent (SNP) | VAF 30/58 reads (52%) | catalogued as rs767244549, COSV56649509; called by muse, mutect2, varscan2
- IRS1 | c.591G>A p.L197= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV59333976; called by muse, mutect2, varscan2
- LDHD | c.564C>G p.L188= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as COSV55580117; called by muse, mutect2, varscan2
- MN1 | c.3762G>A p.Q1254= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as rs1248760599, COSV100180134; called by muse, mutect2, varscan2
- MYF6 | c.594G>A p.V198= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as rs922146355; called by muse, mutect2
- MYH13 | c.576C>T p.V192= | Silent (SNP) | VAF 29/79 reads (37%) | catalogued as COSV52821656; called by muse, mutect2, varscan2
- MYH13 | c.528C>T p.L176= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV52821673; called by muse, mutect2, varscan2
- MYH4 | c.3027G>A p.Q1009= | Silent (SNP) | VAF 62/150 reads (41%) | catalogued as COSV55113057, COSV55117892; called by muse, mutect2, varscan2
- NCF2 | c.813G>A p.K271= | Silent (SNP) | VAF 14/28 reads (50%) | catalogued as COSV62314832; called by muse, mutect2, varscan2
- NIPAL3 | c.901C>T p.L301= | Silent (SNP) | VAF 29/102 reads (28%) | catalogued as COSV50230209; called by muse, mutect2, varscan2
- OR8B3 | c.165C>G p.L55= | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as COSV63541303; called by muse, mutect2, varscan2
- PAK6 | c.177C>T p.I59= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV99545032; called by muse, mutect2
- POLR1A | c.3594G>A p.L1198= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV55689628, COSV55697639; called by muse, mutect2, varscan2
- PTPRA | c.195C>T p.F65= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as COSV53778712, COSV99400736; called by muse, mutect2, varscan2
- RACGAP1 | c.18G>A p.L6= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV56698614; called by muse, mutect2
- RGS6 | c.828T>C p.C276= | Silent (SNP) | VAF 26/67 reads (39%) | catalogued as COSV59566024; called by muse, mutect2, varscan2
- RLIM | c.1125G>C p.V375= | Silent (SNP) | VAF 26/57 reads (46%) | catalogued as COSV60325371; called by muse, mutect2, varscan2
- RUFY3 | c.1092G>A p.E364= | Silent (SNP) | VAF 4/41 reads (10%) | catalogued as COSV99887907; called by muse, mutect2
- SERPINA1 | c.444G>A p.L148= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV63345345; called by muse, mutect2, varscan2
- SLC12A7 | c.1158G>A p.A386= | Silent (SNP) | VAF 38/84 reads (45%) | catalogued as rs370417695, COSV53760271; called by muse, mutect2, varscan2
- WNT9B | c.232C>T p.L78= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as rs1198142966, COSV51517491, COSV99255034; called by muse, mutect2, varscan2
- ZNF532 | c.2742C>T p.F914= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as COSV60171996; called by muse, mutect2, varscan2
- ZNF77 | c.1197G>A p.V399= | Silent (SNP) | VAF 24/41 reads (59%) | catalogued as COSV58821441; called by muse, mutect2, varscan2
- AL133373.3 | n.784G>C | RNA (SNP) | VAF 28/72 reads (39%) | catalogued as rs1566687744; called by muse, mutect2, varscan2
- CLDN16 | c.-164C>G | 5'UTR (SNP) | VAF 9/31 reads (29%) | catalogued as COSV53227009; called by muse, mutect2, varscan2
- METTL16 | n.1069C>T | RNA (SNP) | VAF 21/52 reads (40%) | called by muse, mutect2, varscan2
